Somatic mutation profile of tumor specimen TCGA-DJ-A1QM-01A (aliquot TCGA-DJ-A1QM-01A-11D-A14W-08) from TCGA case TCGA-DJ-A1QM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.2 years (15,418 days).
Specimen TCGA-DJ-A1QM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8592456-626c-403e-9b15-2f595cbd93f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A1QM-10A (Blood Derived Normal), aliquot TCGA-DJ-A1QM-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95797f3b-4b75-491a-b5b5-a8ce9b1e9403

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SLC25A12 | c.1919G>A p.R640K | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV55535234; called by muse, mutect2
- SORBS3 | c.1467G>C p.E489D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.095); catalogued as COSV53554926; called by muse, mutect2, varscan2
- SPATA32 | c.1143C>G p.I381M | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV59305004; called by muse, mutect2
- STAB1 | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.026); catalogued as rs1303207985, COSV58735538; called by muse, mutect2
- PCSK7 | c.1311C>T p.F437= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV58009457; called by muse, mutect2
- SH3GL2 | c.516G>A p.K172= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV101014839; called by muse, mutect2
